Somatic mutation profile of cancer-model specimen HCM-WCMC-1294-C18-85A (3D Organoid; aliquot HCM-WCMC-1294-C18-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-1294-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3; Age at diagnosis: 47.1 years (17,190 days).
Specimen HCM-WCMC-1294-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 737cb7fb-46df-44c8-921b-52639532e951.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1294-C18-10A (Blood Derived Normal), aliquot HCM-WCMC-1294-C18-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb409cc-c3fc-4ed4-982a-ed1879b01d60

The open-access MAF lists 215 somatic variants for this specimen: 149 protein-altering or splice-affecting, 55 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 55, Nonsense Mutation 11, Intron 8, Frame Shift Del 4, Splice Region 2, Splice Site 2, 3'Flank 1, Nonstop Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 216/669 reads (32%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 201/482 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 738/740 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 522/524 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs863223740, CM158377, COSV59281245; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOX2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 438/1031 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs138799827; called by muse, mutect2, varscan2
- ACTB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 167/956 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59316930; called by mutect2, varscan2
- ACTBL2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 59/1246 reads (5%) | catalogued as rs766618791; called by muse, mutect2
- ADAMTS9 | c.5426G>A p.R1809Q | Missense Mutation (SNP) | VAF 539/1050 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150104451; called by muse, mutect2, varscan2
- AGBL4 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 600/919 reads (65%) | catalogued as rs758153531, COSV65761577; called by muse, mutect2, varscan2
- ALG10B | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 203/755 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1446440912; called by muse, mutect2, varscan2
- ALX1 | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 94/1199 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.985); catalogued as COSV57491496; called by muse, mutect2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 828/831 reads (100%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- C21orf58 | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 192/943 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52450133; called by muse, mutect2, varscan2
- CALB2 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 74/837 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56939129; called by muse, mutect2
- CARMIL3 | c.2000C>T p.T667M | Missense Mutation (SNP) | VAF 714/716 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1037045171; called by muse, varscan2
- CATSPERD | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 322/944 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs141589760; called by muse, mutect2, varscan2
- CD1E | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 360/580 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412273037, COSV63769837; called by muse, mutect2, varscan2
- CYP2A7 | c.495C>T p.G165= | Splice Region (SNP) | VAF 471/695 reads (68%) | catalogued as COSV99394197; called by muse, mutect2, varscan2
- DPYD | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 107/710 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64611312; called by muse, mutect2, varscan2
- ESR1 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 27/955 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.142); catalogued as rs1284534841; called by muse, mutect2
- FAM135B | c.3172T>C p.S1058P | Missense Mutation (SNP) | VAF 106/2234 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV52747939; called by muse, mutect2
- FAM162B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 48/1266 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.071); catalogued as rs1471188189, COSV63920835; called by muse, mutect2
- FAT4 | c.5011C>T p.R1671C | Missense Mutation (SNP) | VAF 262/661 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as rs373116363, COSV67881470, COSV67885210; called by muse, mutect2, varscan2
- FCN1 | c.980A>C p.*327Sext*11 | Nonstop Mutation (SNP) | VAF 114/335 reads (34%) | catalogued as rs771767522; called by muse, mutect2, varscan2
- FLT1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 36/754 reads (5%) | catalogued as COSV56716798; called by muse, mutect2
- FSIP2 | c.10210C>T p.R3404W | Missense Mutation (SNP) | VAF 263/716 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs546038705; called by muse, mutect2, varscan2
- GUCD1 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 536/1777 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469775399; called by muse, mutect2, varscan2
- HYDIN | c.10084G>A p.V3362I | Missense Mutation (SNP) | VAF 267/825 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as rs763862190, COSV66877519; called by muse, varscan2
- IHO1 | c.925G>C p.G309R | Missense Mutation (SNP) | VAF 42/1183 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs919052817; called by muse, mutect2
- ISL1 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 202/614 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs552129639, COSV57934722; called by muse, mutect2, varscan2
- ITGB8 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 548/1071 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs574358525; called by muse, mutect2, varscan2
- ITPR2 | c.5545C>T p.R1849* | Nonsense Mutation (SNP) | VAF 325/569 reads (57%) | catalogued as rs1226403397; called by muse, mutect2, varscan2
- KLC1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 107/885 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs535642955, COSV55805302; called by muse, mutect2, varscan2
- LRP1 | c.9853C>T p.R3285C | Missense Mutation (SNP) | VAF 730/730 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1327544994; called by muse, mutect2, varscan2
- LRRIQ1 | c.1221C>A p.N407K | Missense Mutation (SNP) | VAF 170/567 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs373162982, COSV67839431; called by mutect2, varscan2
- MKI67 | c.9697C>G p.P3233A | Missense Mutation (SNP) | VAF 167/741 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as COSV100895968; called by muse, mutect2, varscan2
- MMP2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 116/1254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1369454759, CM1314545; called by muse, mutect2
- MPP7 | c.992A>T p.K331M | Missense Mutation (SNP) | VAF 45/825 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100517647; called by muse, mutect2
- MYH2 | c.5044C>T p.R1682C | Missense Mutation (SNP) | VAF 701/702 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568249919, COSV104393337, COSV55432102, COSV99819620; called by muse, mutect2, varscan2
- OBSCN | c.13180G>T p.G4394C | Missense Mutation (SNP) | VAF 134/1090 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209356254, COSV52770996; called by mutect2, varscan2
- OR10G4 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 522/603 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs536792742, COSV100304745; called by mutect2, varscan2
- OR2AK2 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 68/949 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100823252, COSV63550597; called by muse, mutect2
- PCDH11X | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 754/755 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143617694, COSV53511180; called by muse, mutect2, varscan2
- PCDHB2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 487/1552 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99165985; called by muse, mutect2, varscan2
- PFKFB4 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 398/779 reads (51%) | PolyPhen benign (0.169); catalogued as rs769910590, COSV51679980; called by muse, mutect2, varscan2
- PKNOX1 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 479/482 reads (99%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs746110372; called by muse, mutect2, varscan2
- PTBP1 | c.965C>T p.A322V (on ENST00000349038 / NM_031991.4; = p.A348V on NM_002819.5) | Missense Mutation (SNP) | VAF 247/1123 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs769305979; called by muse, mutect2, varscan2
- RRAS2 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 74/492 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56331645; called by muse, mutect2, varscan2
- SEC14L4 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 602/1092 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs868396334; called by muse, mutect2, varscan2
- SH3PXD2A | c.2917C>T p.R973W (on ENST00000369774 / NM_001365079.1; = p.R945W on NM_014631.2) | Missense Mutation (SNP) | VAF 167/1503 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769506617, COSV60118383; called by muse, mutect2, varscan2
- SLIT3 | c.1159A>G p.N387D | Missense Mutation (SNP) | VAF 77/548 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60607046; called by muse, mutect2, varscan2
- SOCS2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 768/769 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs770266612; called by muse, mutect2, varscan2
- SPANXB1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 528/2514 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.947); catalogued as rs1482019750; called by muse, varscan2
- SV2C | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 345/1002 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368758509; called by muse, mutect2, varscan2
- SYS1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 177/806 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1355256296, COSV54781896; called by muse, mutect2, varscan2
- TBC1D9 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 321/794 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV71309321; called by muse, mutect2, varscan2
- THSD7B | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 199/727 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs545590725, COSV55664839; called by muse, mutect2, varscan2
- TNN | c.1829A>T p.K610M | Missense Mutation (SNP) | VAF 68/766 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99078398; called by muse, mutect2
- TRAV1-1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs758449274; called by muse, mutect2, varscan2
- TRIM64C | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV73267346, COSV73267429; called by muse, mutect2, varscan2
- TRIO | c.6038A>G p.K2013R | Missense Mutation (SNP) | VAF 504/750 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs771683628; called by muse, mutect2, varscan2
- TTN | c.29311G>A p.V9771M (on ENST00000591111; = p.V8844M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/690 reads (30%) | PolyPhen probably damaging (0.955); catalogued as rs771073631; called by muse, mutect2, varscan2
- WDFY3 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 193/435 reads (44%) | catalogued as rs1383600899, COSV99883043; called by muse, mutect2, varscan2
- ZNF354C | c.1379G>T p.R460I | Missense Mutation (SNP) | VAF 268/790 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100203767; called by mutect2, varscan2
- ZNF704 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 132/2000 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as rs1333428713; called by muse, mutect2
- ZNF775 | c.1162C>G p.H388D | Missense Mutation (SNP) | VAF 364/1386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283922578; called by muse, mutect2, varscan2
- ADAM9 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 505/505 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA2A | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 502/1085 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ANKMY1 | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 502/1338 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ARAP2 | c.2006A>C p.D669A | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ARHGAP31 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 327/792 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- BCAR3 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 567/828 reads (68%) | SIFT tolerated (0.68); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BCR | c.2553C>G p.D851E | Missense Mutation (SNP) | VAF 58/2669 reads (2%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.964); called by muse, mutect2
- BICRAL | c.1562del p.G521Efs*11 | Frame Shift Del (DEL) | VAF 142/981 reads (14%) | called by mutect2, pindel, varscan2
- BTNL9 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 98/1288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BVES | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 160/533 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C14orf39 | c.1604T>A p.F535Y | Missense Mutation (SNP) | VAF 52/837 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNG6 | c.589del p.R197Gfs*33 (on ENST00000252729 / NM_145814.1; = p.R126Gfs*33 on NM_031897.2) | Frame Shift Del (DEL) | VAF 111/1312 reads (8%) | called by mutect2, pindel*
- CCDC88B | c.4159A>G p.T1387A | Missense Mutation (SNP) | VAF 85/1348 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- CD276 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 664/664 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CDH23 | c.1178A>G p.N393S | Missense Mutation (SNP) | VAF 189/975 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH23 | c.8777G>C p.G2926A | Missense Mutation (SNP) | VAF 44/1480 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- CIITA | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 147/852 reads (17%) | called by muse, mutect2
- CNNM3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 100/1410 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- CYP4F8 | c.665T>G p.I222S | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DAB1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 152/544 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- DCDC2 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 540/886 reads (61%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRTC1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 286/582 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ECE1 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 758/758 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- EGFLAM | c.2027_2030del p.D676Vfs*40 | Frame Shift Del (DEL) | VAF 402/699 reads (58%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 308/1077 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA1 | c.418+1G>C p.X140_splice | Splice Site (SNP) | VAF 383/740 reads (52%) | called by muse, mutect2, varscan2
- FBXL20 | c.42+1G>T p.X14_splice | Splice Site (SNP) | VAF 56/648 reads (9%) | called by muse, mutect2
- FRMD4A | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 384/787 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FSCB | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 60/1132 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GTPBP1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 622/624 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1A2 | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 454/806 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HPD | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 44/842 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IGLV1-47 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 271/2098 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- INPP4A | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 56/899 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.311); called by muse, mutect2
- INSYN2B | c.1120C>G p.P374A | Missense Mutation (SNP) | VAF 152/881 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KANK2 | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 645/1101 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- KCNA4 | c.1446del p.F483Sfs*38 | Frame Shift Del (DEL) | VAF 112/1091 reads (10%) | called by mutect2, pindel, varscan2
- KEL | c.1494A>C p.I498= | Splice Region (SNP) | VAF 91/1687 reads (5%) | called by muse, mutect2
- LIPA | c.1124T>G p.L375R | Missense Mutation (SNP) | VAF 105/984 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC39 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 35/578 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2
- MGLL | c.463T>C p.S155P (on ENST00000398104 / NM_001003794.2; = p.S165P on NM_007283.6) | Missense Mutation (SNP) | VAF 99/1002 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); called by muse, mutect2
- MYOD1 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 411/974 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NME8 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 37/1061 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- NRXN3 | c.1763A>G p.N588S (on ENST00000557594 / NM_001272020.2; = p.N1012S on NM_004796.6) | Missense Mutation (SNP) | VAF 67/1052 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- NSG2 | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 54/659 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- NUAK1 | c.1818C>G p.N606K | Missense Mutation (SNP) | VAF 265/1058 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NUDT2 | c.437A>T p.E146V | Missense Mutation (SNP) | VAF 36/581 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- NYAP1 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 100/2552 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- OPN5 | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 226/378 reads (60%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13C5 | c.797A>T p.E266V | Missense Mutation (SNP) | VAF 59/799 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- OR5D18 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 393/891 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PCDH15 | c.3982A>C p.K1328Q | Missense Mutation (SNP) | VAF 42/654 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCNX2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 159/566 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PDZD4 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 792/794 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PHLDB1 | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 98/906 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2
- PICALM | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 80/692 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PJA1 | c.372T>A p.D124E | Missense Mutation (SNP) | VAF 112/871 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- POLN | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2, varscan2
- PRLHR | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 114/1049 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PROB1 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 123/1126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRR18 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 153/785 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PTH1R | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 593/1106 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PTPN14 | c.3008A>G p.N1003S | Missense Mutation (SNP) | VAF 422/666 reads (63%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3497A>T p.Y1166F | Missense Mutation (SNP) | VAF 307/1072 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2
- RSPO2 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 291/1829 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.6444T>G p.D2148E | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SLC13A4 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 84/1710 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC5A7 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 112/1134 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2
- SLITRK4 | c.1372T>G p.Y458D | Missense Mutation (SNP) | VAF 118/596 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SORCS3 | c.1291T>A p.S431T | Missense Mutation (SNP) | VAF 405/859 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- STIL | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 508/727 reads (70%) | SIFT tolerated (0.55); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TBCCD1 | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 318/617 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- THSD7A | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 261/1194 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- THSD7B | c.1555A>G p.M519V | Missense Mutation (SNP) | VAF 395/665 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TMEM268 | c.260T>A p.L87* | Nonsense Mutation (SNP) | VAF 237/636 reads (37%) | called by muse, mutect2, varscan2
- ZC3H3 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 835/2716 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF208 | c.3575C>A p.T1192N | Missense Mutation (SNP) | VAF 194/565 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF235 | c.630T>G p.F210L | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF571 | c.1539T>G p.Y513* | Nonsense Mutation (SNP) | VAF 109/892 reads (12%) | called by muse, mutect2, varscan2
- ZNF619 | c.19T>A p.Y7N | Missense Mutation (SNP) | VAF 237/971 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF621 | c.69T>A p.N23K | Missense Mutation (SNP) | VAF 320/583 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF839 | c.735G>T p.E245D (on ENST00000558850 / NM_001267827.1; = p.E361D on NM_018335.5) | Missense Mutation (SNP) | VAF 70/1216 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.083); called by muse, mutect2
- ZSWIM8 | c.3410A>C p.K1137T (on ENST00000605216 / NM_001242487.2; = p.K1142T on NM_015037.3) | Missense Mutation (SNP) | VAF 58/894 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ADGRE1 | c.1401T>C p.I467= | Silent (SNP) | VAF 32/694 reads (5%) | called by muse, mutect2
- AGRP | c.78C>T p.A26= | Silent (SNP) | VAF 59/939 reads (6%) | called by muse, mutect2
- ANO7 | c.1248G>A p.R416= (on ENST00000274979; = p.R362= on NM_001370694.2) | Silent (SNP) | VAF 85/1114 reads (8%) | called by muse, mutect2
- CACNA1G | c.3669C>T p.D1223= | Silent (SNP) | VAF 526/531 reads (99%) | catalogued as rs372686733; called by muse, mutect2, varscan2
- CCDC136 | c.1350G>A p.L450= | Silent (SNP) | VAF 66/1833 reads (4%) | called by muse, mutect2
- CCT8L2 | c.1224G>T p.L408= | Silent (SNP) | VAF 77/1182 reads (7%) | called by muse, mutect2
- CNTN4 | c.438G>A p.P146= | Silent (SNP) | VAF 392/732 reads (54%) | catalogued as rs1281255689, COSV68563395; called by muse, varscan2
- CNTNAP2 | c.792A>T p.S264= | Silent (SNP) | VAF 106/1446 reads (7%) | catalogued as COSV100673364, COSV62265723; called by muse, mutect2
- COA1 | c.423T>C p.D141= | Silent (SNP) | VAF 285/897 reads (32%) | called by muse, mutect2, varscan2
- COL6A1 | c.2733C>T p.N911= | Silent (SNP) | VAF 673/675 reads (100%) | catalogued as rs144585693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRAMP1 | c.351T>C p.A117= | Silent (SNP) | VAF 320/559 reads (57%) | catalogued as rs1365767484; called by muse, mutect2, varscan2
- CREB5 | c.948C>T p.S316= (on ENST00000357727 / NM_182898.4; = p.S309= on NM_004904.3) | Silent (SNP) | VAF 119/3818 reads (3%) | called by muse, mutect2
- CTNNB1 | c.2037C>G p.T679= | Silent (SNP) | VAF 300/1134 reads (26%) | called by muse, mutect2, varscan2
- CTSC | c.390G>A p.L130= | Silent (SNP) | VAF 104/1102 reads (9%) | catalogued as rs1193409020; called by muse, mutect2
- CYP4A22 | c.390C>A p.G130= | Silent (SNP) | VAF 368/581 reads (63%) | catalogued as COSV53740311; called by muse, mutect2, varscan2
- EPAS1 | c.300C>T p.A100= | Silent (SNP) | VAF 703/1391 reads (51%) | catalogued as rs781580686, COSV55384899; called by muse, mutect2, varscan2
- FAM71B | c.255C>T p.D85= | Silent (SNP) | VAF 660/958 reads (69%) | catalogued as rs759977486, COSV57229243; called by muse, mutect2, varscan2
- FAM9B | c.201A>G p.R67= | Silent (SNP) | VAF 43/420 reads (10%) | called by muse, mutect2, varscan2
- FREM2 | c.8727C>T p.S2909= | Silent (SNP) | VAF 62/786 reads (8%) | catalogued as COSV54852480; called by muse, mutect2
- GOLGA3 | c.3717C>T p.D1239= | Silent (SNP) | VAF 82/603 reads (14%) | called by muse, mutect2, varscan2
- KCNH8 | c.1059T>G p.T353= | Silent (SNP) | VAF 81/518 reads (16%) | called by muse, mutect2, varscan2
- LAMA4 | c.1968T>C p.S656= (on ENST00000230538 / NM_001105206.3; = p.S649= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/616 reads (6%) | called by muse, mutect2
- LONP1 | c.1881C>T p.P627= | Silent (SNP) | VAF 342/591 reads (58%) | catalogued as rs778822168; called by muse, mutect2, varscan2
- MAGEC2 | c.708G>A p.V236= | Silent (SNP) | VAF 94/988 reads (10%) | called by muse, mutect2
- MED12 | c.837G>C p.L279= | Silent (SNP) | VAF 70/696 reads (10%) | called by muse, mutect2
- NCOA2 | c.4008C>G p.P1336= | Silent (SNP) | VAF 584/1222 reads (48%) | called by muse, mutect2, varscan2
- NID1 | c.252G>A p.T84= | Silent (SNP) | VAF 88/960 reads (9%) | catalogued as rs200610486; called by muse, mutect2
- NTN1 | c.999C>G p.R333= | Silent (SNP) | VAF 305/620 reads (49%) | catalogued as rs763078951; called by muse, mutect2, varscan2
- OSTC | c.36C>T p.L12= | Silent (SNP) | VAF 66/696 reads (9%) | catalogued as rs564679661; called by muse, mutect2
- OTOG | c.7545C>T p.L2515= | Silent (SNP) | VAF 372/731 reads (51%) | catalogued as rs1260257985; called by muse, mutect2, varscan2
- PCDH11X | c.2643G>A p.L881= | Silent (SNP) | VAF 122/703 reads (17%) | catalogued as rs1367764227; called by muse, mutect2, varscan2
- PCDH17 | c.1539C>T p.P513= | Silent (SNP) | VAF 596/845 reads (71%) | catalogued as rs769843004, COSV64971563; called by muse, mutect2, varscan2
- PCLO | c.13074T>C p.S4358= | Silent (SNP) | VAF 197/1447 reads (14%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1023A>G p.E341= (on ENST00000521381 / NM_181523.3; = p.E71= on NM_181504.4) | Silent (SNP) | VAF 124/533 reads (23%) | catalogued as rs1312971794; called by muse, mutect2, varscan2
- PLXDC2 | c.138C>T p.A46= | Silent (SNP) | VAF 139/727 reads (19%) | called by muse, mutect2, varscan2
- POM121L12 | c.114C>T p.S38= | Silent (SNP) | VAF 361/2241 reads (16%) | catalogued as rs1317131465; called by muse, mutect2, varscan2
- RUNX1T1 | c.843C>T p.G281= (on ENST00000265814 / NM_001198628.1; = p.G254= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/1384 reads (6%) | catalogued as rs369158820; called by muse, mutect2
- SAMD9L | c.4215G>A p.T1405= | Silent (SNP) | VAF 178/1411 reads (13%) | catalogued as rs757486026, COSV59085126; called by muse, mutect2, varscan2
- SLC35F4 | c.837C>T p.S279= (on ENST00000339762 / NM_001352015.2; = p.S243= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 811/811 reads (100%) | catalogued as rs773295044, COSV100333911; called by muse, mutect2, varscan2
- SLCO5A1 | c.2112C>T p.Y704= | Silent (SNP) | VAF 33/1073 reads (3%) | called by muse, mutect2
- SMG1 | c.9543C>T p.T3181= | Silent (SNP) | VAF 119/865 reads (14%) | catalogued as COSV67175369; called by muse, mutect2, varscan2
- SPATA5 | c.2625G>A p.E875= | Silent (SNP) | VAF 64/660 reads (10%) | called by muse, mutect2
- TARS3 | c.216G>T p.R72= | Silent (SNP) | VAF 103/810 reads (13%) | catalogued as rs1358480555; called by muse, mutect2, varscan2
- TCF20 | c.3366T>C p.S1122= | Silent (SNP) | VAF 892/892 reads (100%) | called by muse, mutect2, varscan2
- TLR10 | c.1164T>C p.S388= | Silent (SNP) | VAF 222/447 reads (50%) | called by muse, mutect2, varscan2
- TP73 | c.1668C>T p.T556= | Silent (SNP) | VAF 165/1092 reads (15%) | catalogued as rs145718621; called by muse, mutect2, varscan2
- TRIM32 | c.948C>T p.A316= | Silent (SNP) | VAF 80/908 reads (9%) | catalogued as rs1351064837; called by muse, mutect2
- TSPOAP1 | c.4764C>T p.D1588= | Silent (SNP) | VAF 443/443 reads (100%) | catalogued as rs769090851, COSV52114848; called by muse, mutect2, varscan2
- TTN | c.65901G>C p.V21967= (on ENST00000591111; = p.V14543= on NM_003319.4) | Silent (SNP) | VAF 278/932 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.2916G>A p.P972= (on ENST00000591111; = p.P926= on NM_003319.4) | Silent (SNP) | VAF 381/958 reads (40%) | catalogued as rs757569345, COSV59895929; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UGT3A1 | c.1353C>T p.P451= | Silent (SNP) | VAF 328/1009 reads (33%) | catalogued as COSV57100013; called by muse, mutect2, varscan2
- UNC5C | c.2589C>G p.G863= | Silent (SNP) | VAF 192/573 reads (34%) | called by muse, mutect2, varscan2
- USP29 | c.2442G>T p.V814= | Silent (SNP) | VAF 578/913 reads (63%) | catalogued as COSV54142951; called by muse, mutect2, varscan2
- ZC3H6 | c.534A>G p.K178= | Silent (SNP) | VAF 73/1092 reads (7%) | called by muse, mutect2
- ZSCAN20 | c.1365C>T p.N455= | Silent (SNP) | VAF 686/687 reads (100%) | catalogued as rs145571481, COSV63683794; called by muse, varscan2
- CASR | c.1378-6079T>A | Intron (SNP) | VAF 30/574 reads (5%) | called by muse, mutect2
- GNA12 | c.310-19779G>T | Intron (SNP) | VAF 335/733 reads (46%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6563A>G | Intron (SNP) | VAF 90/832 reads (11%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6564G>T | Intron (SNP) | VAF 102/942 reads (11%) | called by muse, mutect2
- NAA15 | chr4:139393702 C>G | 3'Flank (SNP) | VAF 61/465 reads (13%) | called by muse, varscan2
- NPEPL1 | chr20:58691452 C>G | 5'Flank (SNP) | VAF 138/608 reads (23%) | called by muse, mutect2, varscan2
- NRSN1 | c.190-4506G>A | Intron (SNP) | VAF 91/670 reads (14%) | catalogued as rs1483276291; called by muse, mutect2, varscan2
- SERF2 | c.117-41C>A | Intron (SNP) | VAF 398/1128 reads (35%) | called by muse, mutect2, varscan2
- SLC22A17 | n.531C>T | RNA (SNP) | VAF 112/1316 reads (9%) | catalogued as rs1172495305; called by muse, mutect2
- VIT | c.487+9T>G | Intron (SNP) | VAF 88/1470 reads (6%) | catalogued as COSV64895212; called by muse, mutect2
- ZMYND8 | c.-46-1956C>T | Intron (SNP) | VAF 223/960 reads (23%) | called by muse, mutect2, varscan2
